Somatic mutation profile of tumor specimen TCGA-P4-A5E7-01A (aliquot TCGA-P4-A5E7-01A-31D-A28G-10) from TCGA case TCGA-P4-A5E7, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.0 years (27,029 days).
Specimen TCGA-P4-A5E7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaf393fd-1b5e-4675-ac0c-1f8ad120a5d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-A5E7-11A (Solid Tissue Normal), aliquot TCGA-P4-A5E7-11A-11D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25eff8e7-ce53-4f51-b726-b828faf340fc

The open-access MAF lists 100 somatic variants for this specimen: 77 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Frame Shift Del 14, Nonsense Mutation 4, 3'Flank 3, Splice Region 2, Frame Shift Ins 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by muse, mutect2
- AHNAK | c.3973A>G p.M1325V | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as rs1278538520, COSV57205373; called by muse, mutect2, varscan2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2, varscan2
- ANKMY1 | c.1068G>A p.Q356= | Splice Region (SNP) | VAF 41/113 reads (36%) | catalogued as COSV56030799; called by muse, mutect2, varscan2
- ARHGAP31 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51789706; called by muse, mutect2, varscan2
- ATP12A | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372819883; called by muse, mutect2, varscan2
- AUTS2 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs777840526, COSV61384387, COSV61427591; called by muse, mutect2, varscan2
- BABAM1 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63920005; called by muse, mutect2, varscan2
- BAZ1B | c.3335T>C p.F1112S | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV59989087; called by muse, mutect2, varscan2
- BPIFA1 | c.662del p.G221Afs*26 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | catalogued as COSV62825140; called by mutect2, pindel, varscan2
- BTBD11 | c.2855T>G p.L952R (on ENST00000280758 / NM_001018072.2; = p.L489R on NM_001017523.2) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55018379; called by muse, mutect2, varscan2
- CCDC40 | c.1709C>A p.T570N | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV66473061; called by muse, mutect2, varscan2
- CEP78 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs757714365, COSV52845771; called by muse, varscan2
- COL12A1 | c.4976C>A p.T1659K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59390673; called by muse, mutect2, varscan2
- CRB2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs756949939, COSV63501974; called by muse, mutect2, varscan2
- EEF1G | c.611T>G p.L204W | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV61321008; called by muse, mutect2, varscan2
- ETHE1 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52677083; called by muse, mutect2, varscan2
- ETHE1 | c.231T>A p.N77K | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52677093; called by muse, mutect2, varscan2
- EVI5L | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV54484107; called by muse, mutect2, varscan2
- FOXK1 | c.853A>C p.K285Q | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as COSV61064652; called by muse, mutect2, varscan2
- GOLGB1 | c.4138C>T p.Q1380* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV61462337; called by muse, mutect2, varscan2
- GON4L | c.5825G>C p.G1942A | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.444); catalogued as COSV55188147; called by muse, mutect2, varscan2
- HCRTR2 | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV63794110; called by muse, mutect2, varscan2
- INKA1 | c.621A>C p.E207D | Missense Mutation (SNP) | VAF 135/277 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV58525825; called by muse, mutect2, varscan2
- IRX3 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.168); catalogued as rs958132177, COSV61667883; called by muse, mutect2, varscan2
- JAG1 | c.246T>G p.Y82* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as CM146064, COSV54754027; called by muse, mutect2, varscan2
- KCNIP3 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54666209; called by muse, mutect2
- KCNMA1 | c.3254G>C p.G1085A (on ENST00000286628 / NM_001161352.2; = p.G1027A on NM_002247.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV54231635; called by muse, mutect2, varscan2
- KIAA0930 | c.679G>A p.A227T (on ENST00000336156 / NM_001009880.2; = p.A232T on NM_015264.2) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV52662234; called by muse, mutect2, varscan2
- KIF1B | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV55804287; called by muse, mutect2, varscan2
- KIFC2 | c.1339C>A p.R447S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs748782569, COSV56760163; called by muse, mutect2, varscan2
- KMT2C | c.13021G>T p.G4341W | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV51346140; called by muse, mutect2, varscan2
- KRT2 | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59009321; called by muse, mutect2, varscan2
- MUC6 | c.4733C>T p.P1578L | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs769245466, COSV70135685; called by muse, varscan2
- MYL12B | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52898222; called by muse, varscan2
- NFKBIL1 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.077); catalogued as COSV65990191; called by muse, mutect2, varscan2
- NQO2 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.814); catalogued as COSV57642395; called by muse, mutect2, varscan2
- NRAS | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as COSV54740128, COSV99794696; called by muse, mutect2, varscan2
- OIT3 | c.1622T>G p.I541S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61825237; called by muse, mutect2, varscan2
- PDZD8 | c.2285C>A p.P762H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57823704; called by muse, mutect2, varscan2
- PLXDC2 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65901298; called by mutect2, varscan2
- PTEN | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs786201758, COSV64291005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRN | c.1589T>A p.V530E | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55346016; called by muse, mutect2, varscan2
- RAPGEF2 | c.3149T>C p.I1050T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV52425378; called by muse, mutect2, varscan2
- RBP1 | c.321G>T p.W107C (on ENST00000619087 / NM_001365940.2; = p.W169C on NM_002899.5) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51675762; called by muse, mutect2, varscan2
- REST | c.2802A>C p.L934F | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58359551; called by muse, mutect2, varscan2
- SLC5A7 | c.152T>A p.L51* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV50889239; called by muse, mutect2, varscan2
- SRRM4 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV57409804; called by muse, mutect2, varscan2
- SSB | c.938A>C p.E313A | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs777853278, COSV53626003; called by muse, mutect2, varscan2
- SUCLG1 | c.1014G>A p.K338= | Splice Region (SNP) | VAF 32/108 reads (30%) | catalogued as COSV67264795, COSV67265985; called by muse, mutect2, varscan2
- SUGP2 | c.3054G>A p.M1018I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58255706; called by muse, mutect2, varscan2
- TET1 | c.35T>C p.L12S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV65382451; called by muse, mutect2, varscan2
- TMEM38A | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV51818219; called by muse, mutect2, varscan2
- TTC27 | c.1692G>A p.W564* | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | catalogued as rs778891641, COSV58649237; called by muse, mutect2, varscan2
- UFSP2 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV52990623; called by muse, mutect2, varscan2
- VDAC3 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV50081276; called by muse, mutect2, varscan2
- ZBTB22 | c.427T>C p.C143R | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56467010; called by muse, mutect2, varscan2
- ZC3H12A | c.1633A>T p.R545W | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV66103927, COSV66104117; called by muse, mutect2, varscan2
- ZNF75A | c.63T>A p.D21E | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs755434992, COSV73039572, COSV73039582; called by muse, mutect2, varscan2
- CCDC181 | c.951del p.N318Ifs*12 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- ECPAS | c.5312del p.N1771Ifs*7 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- GPR179 | c.1097G>A p.S366N (on ENST00000621958; = p.S365N on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- HOOK2 | c.1954del p.S652Afs*60 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | called by mutect2, pindel, varscan2
- KLRC2 | c.64del p.R22Gfs*20 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, varscan2
- KLRC3 | c.64del p.R22Gfs*20 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, varscan2
- KMT2C | c.8655_8656del p.E2885Dfs*39 | Frame Shift Del (DEL) | VAF 84/175 reads (48%) | called by mutect2, pindel, varscan2
- MRPL45 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- NUP62 | c.1432_1449del p.L478_D483del | In Frame Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.988dup p.D330Gfs*3 (on ENST00000521381 / NM_181523.3; = p.D60Gfs*3 on NM_181504.4) | Frame Shift Ins (INS) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- PRKCG | c.1255del p.Q419Sfs*15 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- PRPF4B | c.551_566del p.S184Kfs*92 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- REXO5 | c.1558del p.A520Lfs*2 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- RSPH3 | c.1432_1433del p.H478Sfs*8 (on ENST00000252655; = p.H336Sfs*8 on NM_031924.8) | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by pindel, varscan2
- SLC7A13 | c.720del p.K240Nfs*10 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- THSD7A | c.2726_2727insA p.T910Dfs*17 | Frame Shift Ins (INS) | VAF 70/165 reads (42%) | called by mutect2, pindel, varscan2
- TTLL5 | c.2360del p.N787Tfs*18 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- VPS13D | c.7165del p.S2389Pfs*5 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- ACADVL | c.1572T>C p.L524= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as COSV50034783; called by muse, mutect2, varscan2
- ARMC8 | c.1227C>T p.H409= (on ENST00000469044 / NM_001363941.2; = p.H395= on NM_015396.6) | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV58616875; called by muse, mutect2, varscan2
- CBY1 | c.141G>A p.L47= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs1271083731, COSV53263941; called by muse, mutect2, varscan2
- CUX1 | c.3786G>A p.A1262= | Silent (SNP) | VAF 90/147 reads (61%) | catalogued as rs140169027, COSV52919615; called by muse, mutect2, varscan2
- DDR2 | c.750G>A p.V250= | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as rs1261964297, COSV63369633; called by muse, mutect2, varscan2
- DENND5B | c.3081G>A p.G1027= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1385048226, COSV60900273; called by muse, mutect2, varscan2
- DZANK1 | c.777G>A p.L259= (on ENST00000262547 / NM_001099407.1; = p.L60= on NM_018152.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1163392197, COSV52748113, COSV99362711; called by muse, mutect2, varscan2
- FAM98A | c.498A>G p.Q166= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs561820764, COSV53208861; called by muse, mutect2, varscan2
- KCNIP3 | c.90C>T p.I30= | Silent (SNP) | VAF 103/347 reads (30%) | catalogued as rs778205763, COSV54666227; called by muse, mutect2
- LINGO2 | c.171C>T p.I57= | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as rs1363968993, COSV58057729; called by muse, mutect2, varscan2
- MDM1 | c.1767A>T p.I589= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV57444752; called by muse, mutect2, varscan2
- NPAP1 | c.2328C>T p.A776= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs761682423, COSV61504992, COSV61512003; called by muse, mutect2, varscan2
- POLR2A | c.2301G>A p.K767= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs1198974510; called by muse, mutect2, varscan2
- RABGGTA | c.1632G>A p.P544= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs369935041; called by muse, mutect2, varscan2
- RALGAPA1 | c.3243T>G p.P1081= | Silent (SNP) | VAF 59/156 reads (38%) | catalogued as COSV51877684; called by muse, mutect2, varscan2
- TNS1 | c.4446G>C p.P1482= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV50691310, COSV50692034; called by muse, mutect2, varscan2
- TRPC4AP | c.1026C>A p.A342= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as COSV52677332; called by muse, mutect2, varscan2
- TTC31 | c.669G>A p.Q223= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV52034369; called by muse, mutect2, varscan2
- UNC13A | c.786C>A p.R262= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53189509; called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593105 T>C | 3'Flank (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2
- MIR9-1 | chr1:156416824 C>A | 3'Flank (SNP) | VAF 38/140 reads (27%) | catalogued as COSV59483145; called by muse, mutect2, varscan2
- SSX6P | chrX:48117109 G>C | 3'Flank (SNP) | VAF 143/510 reads (28%) | called by muse, mutect2, varscan2
- VPS13B | c.4820+15849_4820+15867del | Intron (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
